Somatic mutation profile of tumor specimen ALCH-ADZP-TTP1-A (aliquot ALCH-ADZP-TTP1-A-1-0-D-A603-36) from ALCHEMIST case ALCH-ADZP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.5 years (25,768 days).
Specimen ALCH-ADZP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca4807fb-8078-4a55-be60-688b14ffb859.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADZP-NB1-A (Blood Derived Normal), aliquot ALCH-ADZP-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d846a33-ea3c-41af-86bf-f69a9c9a0325

The open-access MAF lists 164 somatic variants for this specimen: 118 protein-altering or splice-affecting, 26 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 26, Frame Shift Del 7, Intron 6, 5'Flank 4, Splice Site 4, 3'UTR 4, Nonsense Mutation 4, RNA 2, 3'Flank 2, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 92/436 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACVR1B | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57777541; called by muse, mutect2, varscan2
- ARMC2 | c.1305G>C p.K435N | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV64552188; called by muse, mutect2
- C1GALT1C1L | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56751616; called by muse, mutect2
- CHST2 | c.1548G>T p.E516D | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs918181585; called by muse, mutect2
- CYP2W1 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV100417330; called by muse, mutect2, varscan2
- DNAH2 | c.9672G>T p.L3224F | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as rs945541809; called by muse, mutect2
- DNM3 | c.2582G>A p.R861H (on ENST00000355305 / NM_001350206.2; = p.R855H on NM_015569.5) | Missense Mutation (SNP) | VAF 75/455 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs183558699, COSV100797740; called by muse, mutect2, varscan2
- DYNC2H1 | c.2617G>T p.E873* | Nonsense Mutation (SNP) | VAF 46/221 reads (21%) | catalogued as COSV62089653; called by muse, mutect2, varscan2
- DYRK2 | c.1133G>A p.R378H (on ENST00000344096 / NM_006482.3; = p.R305H on NM_003583.4) | Missense Mutation (SNP) | VAF 95/441 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs543503984, COSV59845139, COSV59845482; called by muse, mutect2, varscan2
- EIF4A2 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.353); catalogued as COSV100125562, COSV60624891; called by muse, mutect2
- ERBB4 | c.2597G>C p.R866T | Missense Mutation (SNP) | VAF 19/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61486132; called by muse, mutect2
- FAM120C | c.2786G>A p.R929Q | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.059); catalogued as rs782597475, COSV60258025, COSV60259125; called by muse, mutect2
- FREM1 | c.2714G>T p.G905V | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as COSV66518804; called by muse, mutect2
- GCSAML | c.94del p.E32Kfs*2 | Frame Shift Del (DEL) | VAF 20/128 reads (16%) | catalogued as COSV100826055; called by mutect2, pindel, varscan2
- GOLGB1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV61463189; called by muse, mutect2
- HDGFL3 | c.554C>A p.A185E | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.084); catalogued as COSV55207291; called by muse, mutect2
- HNRNPA2B1 | c.7-3dup | Splice Region (INS) | VAF 26/202 reads (13%) | catalogued as rs759915055; called by mutect2, pindel, varscan2
- IRX1 | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV57358695; called by muse, mutect2, varscan2
- KIF2B | c.287C>G p.S96C | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV52129533; called by muse, mutect2, varscan2
- MMP20 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 72/486 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs147615125; called by muse, varscan2
- MYO18A | c.4130G>A p.R1377Q | Missense Mutation (SNP) | VAF 75/178 reads (42%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs764696018; called by muse, mutect2, varscan2
- NLRP4 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100016318; called by muse, mutect2, varscan2
- OR5D14 | c.455T>A p.L152H | Missense Mutation (SNP) | VAF 43/218 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.895); catalogued as rs751581338, COSV59457743; called by muse, mutect2, varscan2
- PCDH7 | c.3095G>T p.G1032V | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV100688008; called by muse, mutect2, varscan2
- PDK2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs769477192; called by muse, mutect2, varscan2
- PPL | c.4297G>T p.E1433* | Nonsense Mutation (SNP) | VAF 6/77 reads (8%) | catalogued as rs889396569, COSV99277889; called by muse, mutect2
- PTPRK | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV63888698; called by muse, mutect2
- RHOA | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV69043890; called by muse, mutect2
- RP1 | c.3119T>C p.I1040T | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs1251985216; called by muse, mutect2, varscan2
- SAMD9 | c.4247G>A p.R1416Q | Missense Mutation (SNP) | VAF 109/743 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs778841567; called by muse, mutect2, varscan2
- SLURP1 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 72/282 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs139944345; called by muse, mutect2, varscan2
- SSBP2 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100283134; called by muse, mutect2
- TAOK1 | c.706C>A p.H236N | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55594672; called by muse, mutect2
- TAS2R16 | c.866del p.G289Efs*? | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as COSV50797088, COSV50799254; called by mutect2, pindel
- TRRAP | c.11270G>A p.R3757Q (on ENST00000359863 / NM_001244580.1; = p.R3728Q on NM_003496.3) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs987263983, COSV100705480; called by muse, mutect2
- TTBK1 | c.2504C>T p.T835M | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1356628856; called by muse, mutect2
- VEGFC | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 27/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373412644; called by muse, mutect2, varscan2
- ZNF492 | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs909524574; called by muse, mutect2, varscan2
- ZSCAN30 | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 71/332 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs936216937; called by muse, mutect2, varscan2
- ACVR1 | c.1306C>G p.P436A | Missense Mutation (SNP) | VAF 95/542 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ADAMTS19 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.137); called by muse, mutect2
- AHRR | c.3_25del p.M1_?9 | Frame Shift Del (DEL) | VAF 20/208 reads (10%) | called by mutect2, pindel
- AKAP12 | c.4537G>C p.D1513H | Missense Mutation (SNP) | VAF 10/235 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ALDH6A1 | c.834G>C p.K278N | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH7A1 | c.1516A>T p.R506W | Missense Mutation (SNP) | VAF 139/584 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP5PO | c.565A>T p.I189F | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CAMSAP3 | c.3272A>C p.D1091A | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CATSPER4 | c.358A>G p.K120E | Missense Mutation (SNP) | VAF 19/307 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- CCDC88C | c.4505C>T p.A1502V | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CDC20B | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2
- CDH9 | c.1748C>A p.T583K | Missense Mutation (SNP) | VAF 125/560 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD8 | c.4817+1G>T p.X1606_splice (on ENST00000646647 / NM_001170629.2; = p.X1327_splice on NM_020920.4) | Splice Site (SNP) | VAF 48/217 reads (22%) | called by muse, mutect2, varscan2
- CHRNB1 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 29/570 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLSTN3 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- COL13A1 | c.858_861del p.H286Qfs*56 (on ENST00000398978 / NM_001130103.2; = p.H229Qfs*56 on NM_080798.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | called by mutect2, pindel
- CPNE8 | c.185_186del p.E62Vfs*5 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | called by pindel, varscan2
- CPS1 | c.1939G>C p.V647L | Missense Mutation (SNP) | VAF 62/319 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACD | c.1911C>A p.N637K | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CUL7 | c.3657G>C p.Q1219H | Missense Mutation (SNP) | VAF 15/318 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- DEDD2 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DENND4B | c.3898A>G p.I1300V | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2
- DLGAP3 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DNAH8 | c.6836T>G p.L2279W | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPAS1 | c.2287+2T>A p.X763_splice | Splice Site (SNP) | VAF 20/306 reads (7%) | called by muse, mutect2
- EPHX4 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- FANCM | c.4214C>G p.S1405C | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- FCRL1 | c.1287G>T p.M429I | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- FGF6 | c.525G>T p.L175F | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- FGGY | c.1346T>C p.I449T | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- FTH1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 30/680 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- GIGYF2 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 15/435 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- GSDME | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GTF3C1 | c.3344G>T p.G1115V | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HOOK2 | c.406A>G p.M136V | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IDO1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2
- IGSF22 | c.1642_1656del p.K548_E552del | In Frame Del (DEL) | VAF 28/194 reads (14%) | called by pindel, varscan2
- IKBKG | c.518+1G>C p.X173_splice | Splice Site (SNP) | VAF 21/192 reads (11%) | called by muse, mutect2, varscan2
- INSR | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 95/584 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- INTS2 | c.1402A>C p.S468R | Missense Mutation (SNP) | VAF 113/289 reads (39%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- JDP2 | c.324A>T p.E108D | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- JMJD1C | c.2468_2483del p.L823* | Frame Shift Del (DEL) | VAF 14/186 reads (8%) | called by mutect2, pindel
- KIAA1109 | c.9971C>T p.S3324L | Missense Mutation (SNP) | VAF 38/475 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- LRBA | c.1072T>G p.C358G | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRCH1 | c.941T>G p.V314G | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.218); called by muse, mutect2
- MALRD1 | c.3458C>G p.S1153C | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- MRPL47 | c.418G>T p.D140Y | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- MUC7 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2
- NLRP10 | c.128del p.P43Hfs*10 | Frame Shift Del (DEL) | VAF 68/399 reads (17%) | called by mutect2, pindel, varscan2
- OR52B2 | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5AK2 | c.722G>A p.C241Y | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PGF | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PITX1 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHG2 | c.2844G>T p.Q948H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PLEKHG2 | c.2845G>T p.A949S | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHO1 | c.275A>G p.H92R | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- PLPP5 | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- PPL | c.3484G>C p.E1162Q | Missense Mutation (SNP) | VAF 23/264 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2
- PSMD4 | c.826C>A p.P276T | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.351); called by muse, mutect2
- SAMD9L | c.3866A>T p.E1289V | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYL2 | c.1898A>G p.E633G | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.11); called by muse, mutect2
- SLC39A10 | c.2123G>T p.C708F | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNRNP70 | c.796T>A p.S266T | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2
- SRRM1 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SUCNR1 | c.406A>C p.K136Q | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TBC1D20 | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- TBXAS1 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2
- TRIM31 | c.883+1G>C p.X295_splice | Splice Site (SNP) | VAF 55/120 reads (46%) | called by muse, mutect2, varscan2
- TRPM6 | c.3406C>A p.L1136I | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- UBXN7 | c.976A>C p.S326R | Missense Mutation (SNP) | VAF 44/410 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- UNC119 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 78/202 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XPO7 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 53/189 reads (28%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8509T>A p.L2837M | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ZNF202 | c.987G>T p.E329D | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.094); called by muse, varscan2
- ZNF22 | c.182A>T p.E61V | Missense Mutation (SNP) | VAF 40/258 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ZNF285 | c.1391A>T p.D464V | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ZNF404 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, varscan2
- ZNF404 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.409); called by muse, varscan2
- ANAPC7 | c.25T>C p.L9= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- ATP5F1B | c.258G>T p.L86= | Silent (SNP) | VAF 53/176 reads (30%) | called by muse, mutect2, varscan2
- BAAT | c.498G>A p.L166= | Silent (SNP) | VAF 18/348 reads (5%) | catalogued as COSV99408465; called by muse, mutect2
- BBS10 | c.663G>A p.L221= | Silent (SNP) | VAF 18/300 reads (6%) | called by muse, mutect2
- BHLHE23 | c.342C>T p.H114= (on ENST00000370346; = p.H130= on NM_080606.4) | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as rs564736053, COSV100947585; called by muse, mutect2, varscan2
- CATSPERG | c.1248A>G p.L416= | Silent (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- CCNB1 | c.627A>G p.L209= | Silent (SNP) | VAF 21/262 reads (8%) | called by muse, mutect2
- CDH7 | c.372G>A p.A124= | Silent (SNP) | VAF 28/572 reads (5%) | catalogued as rs375091808; called by muse, mutect2
- CHRM2 | c.306G>A p.L102= | Silent (SNP) | VAF 123/796 reads (15%) | called by muse, mutect2, varscan2
- CUL9 | c.3081G>A p.E1027= | Silent (SNP) | VAF 51/228 reads (22%) | catalogued as rs1374285397; called by muse, mutect2, varscan2
- FAM13A | c.1899A>G p.T633= | Silent (SNP) | VAF 26/249 reads (10%) | called by muse, mutect2, varscan2
- GABRA5 | c.36C>T p.I12= | Silent (SNP) | VAF 37/199 reads (19%) | called by muse, mutect2, varscan2
- HMGN1 | c.102G>A p.A34= | Silent (SNP) | VAF 22/360 reads (6%) | catalogued as rs1212952107, COSV55742325, COSV99903284; called by muse, mutect2
- HSPA12B | c.865C>A p.R289= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV53925771; called by muse, mutect2, varscan2
- OR52A1 | c.807T>A p.S269= | Silent (SNP) | VAF 44/239 reads (18%) | called by muse, mutect2, varscan2
- OR8K3 | c.741C>A p.V247= | Silent (SNP) | VAF 52/284 reads (18%) | called by muse, mutect2, varscan2
- PLPPR2 | c.465G>T p.T155= | Silent (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- PTPRU | c.2937G>A p.E979= | Silent (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- RAN | c.183C>T p.F61= | Silent (SNP) | VAF 14/342 reads (4%) | catalogued as rs1485935299; called by muse, mutect2
- SH2D4A | c.1185C>T p.L395= | Silent (SNP) | VAF 12/374 reads (3%) | catalogued as rs1243149729; called by muse, mutect2
- SIM1 | c.1458G>A p.R486= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs749913988; called by muse, mutect2, varscan2
- SMURF2 | c.1029A>G p.Q343= | Silent (SNP) | VAF 7/191 reads (4%) | catalogued as rs782229091; called by muse, mutect2
- TMEM86A | c.126C>T p.I42= | Silent (SNP) | VAF 46/328 reads (14%) | called by muse, mutect2, varscan2
- USP40 | c.2734C>T p.L912= | Silent (SNP) | VAF 17/142 reads (12%) | called by muse, varscan2
- WT1 | c.1239C>T p.F413= | Silent (SNP) | VAF 55/626 reads (9%) | catalogued as COSV60085021; called by muse, mutect2
- ZNF354A | c.873C>A p.T291= | Silent (SNP) | VAF 55/243 reads (23%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501295 A>G | 5'Flank (SNP) | VAF 38/169 reads (22%) | called by muse, varscan2
- ASH1L | chr1:155563422 C>T | 5'Flank (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2, varscan2
- CD200 | c.*43G>T | 3'UTR (SNP) | VAF 11/242 reads (5%) | called by muse, mutect2
- CLPTM1L | c.1315+21G>T | Intron (SNP) | VAF 47/326 reads (14%) | called by muse, varscan2
- FCN1 | c.*266C>T | 3'UTR (SNP) | VAF 35/171 reads (20%) | catalogued as rs757694931; called by muse, mutect2, varscan2
- FOXD4L5 | chr9:65288502 G>A | 5'Flank (SNP) | VAF 45/335 reads (13%) | called by muse, mutect2, varscan2
- GVINP1 | n.6237G>T | RNA (SNP) | VAF 26/99 reads (26%) | called by muse, mutect2, varscan2
- NCOR1 | c.*3102T>C | 3'UTR (SNP) | VAF 11/288 reads (4%) | called by muse, mutect2
- NICN1 | c.601-23C>T | Intron (SNP) | VAF 14/272 reads (5%) | catalogued as rs1389596806; called by muse, mutect2
- PIK3R3 | chr1:46132729 G>A | 5'Flank (SNP) | VAF 13/64 reads (20%) | catalogued as rs746406046; called by muse, varscan2
- PRDM11 | chr11:45226812 G>T | 3'Flank (SNP) | VAF 31/160 reads (19%) | catalogued as rs1366996961; called by muse, mutect2, varscan2
- RPS4XP21 | n.391T>C | RNA (SNP) | VAF 39/185 reads (21%) | called by muse, mutect2, varscan2
- SLC25A21 | c.-48_-45del | 5'UTR (DEL) | VAF 15/87 reads (17%) | called by mutect2, pindel, varscan2
- SLITRK1 | c.*17G>C | 3'UTR (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- TEFM | c.645+36G>C | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- TPSD1 | chr16:1262475 C>A | 3'Flank (SNP) | VAF 42/249 reads (17%) | called by muse, mutect2, varscan2
- TYMP | c.646+109del | Intron (DEL) | VAF 11/74 reads (15%) | called by mutect2, pindel, varscan2
- VKORC1 | c.173+177G>C | Intron (SNP) | VAF 14/188 reads (7%) | catalogued as COSV56231803, COSV56232505; called by muse, mutect2
- VPS35 | c.-44C>G | 5'UTR (SNP) | VAF 15/92 reads (16%) | catalogued as COSV54480298; called by muse, mutect2, varscan2
- ZMYND8 | c.26-8635C>T | Intron (SNP) | VAF 30/360 reads (8%) | called by muse, mutect2
